Gene-level copy-number profile of tumor specimen TCGA-14-2554-01A from TCGA case TCGA-14-2554, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-14-2554-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.541815c8-c9e3-44b9-9f70-3b2a1e137033.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-2554-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/165fd25f-23e9-4159-a728-090f99cec6d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,807; copy number 2: 42,822; copy number 3: 13,084; copy number 4: 46; copy number 14: 42; copy number 41: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-2554-01A-01D-0784-01): tumor purity 0.81, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,115,488–15,400,283, 42 genes, copy number 14 (within-gene range 2–14): HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2, KAZN, RNU6-1265P, AL357873.1, KAZN-AS1, TBCAP2, AL031293.1, TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2.
- chr7:54,759,348–55,211,628, 4 genes, copy number 41 (within-gene range 3–41): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 3,807. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
